Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A01W, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A01W-01A (Primary Tumor).

Sample ID #

Diagnosis:

This is a poorly differentiated adenocarcinoma of the rectum with histopathological grade G3 differentiation / with ulceration of the inner tumor surface, tumor infiltration of the parietal layers of the rectum as far as the perirectal fatty connective tissue with carcinomatous lymphangiosis and hemangiosis, with peritumorous, chronic recurrent concomitant inflammation, with similarly differentiated areas of adenocarcinoma in the attached piece of tissue, with moderate chronic lymphadenitis of the tumor-free lymph nodes (0/20), tumor-free overview sections from the resection margins and from the anastomosis ring, and also hyperplastic polyps of the colon mucosa, as well as tubular adenomas (in the macroscopically described polypous areas of mucosa).

According to these prepared sections, the tumor spread of the rectal carcinoma corresponds to a tumor classification pT3, pN0, Mx, L1, V1

12+

1CD-0-3

Adenocarcinoma, NOS 8140/3

Site: rectum, NOS C30.9

per 3/21/11

IIIP-A Discrepancy		☒

Source: NCI Genomic Data Commons file 53f87083-1ab8-4d3e-b0cf-315723f2329f (TCGA-AG-A01W.A42A2BFF-5C8A-428A-A9AB-F11B25CCC340.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).